Somatic mutation profile of tumor specimen TCGA-B0-5108-01A (aliquot TCGA-B0-5108-01A-01D-1421-08) from TCGA case TCGA-B0-5108, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 54.6 years (19,932 days).
Specimen TCGA-B0-5108-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc838a03-cb4a-4467-b3a1-10917fad60b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5108-11A (Solid Tissue Normal), aliquot TCGA-B0-5108-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a0b53ae-ab1a-436f-9046-43003b2244fe

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMY2A | c.39C>A p.C13* | Nonsense Mutation (SNP) | VAF 69/449 reads (15%) | catalogued as COSV70214472; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV63437806; called by muse, mutect2, varscan2
- ASXL1 | c.4622G>C p.R1541T | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60107259; called by muse, mutect2, varscan2
- ASXL3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.432); catalogued as COSV52464571; called by muse, mutect2, varscan2
- CD44 | c.436+2T>A p.X146_splice | Splice Site (SNP) | VAF 45/245 reads (18%) | catalogued as COSV53529182; called by muse, mutect2, varscan2
- CENPE | c.6632A>G p.K2211R | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV54380572; called by muse, mutect2, varscan2
- CFAP36 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55404214; called by mutect2, varscan2
- CWC22 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1358556296, COSV55428311; called by muse, mutect2, varscan2
- ELN | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as rs531144748, COSV52709766; called by muse, mutect2
- FREM2 | c.6160T>C p.S2054P | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1282941073, COSV54836298; called by muse, mutect2, varscan2
- GRID2 | c.2251A>T p.I751F | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV56192193; called by muse, mutect2, varscan2
- GUCY2C | c.770A>T p.K257M | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV53789595; called by muse, mutect2, varscan2
- KRT16 | c.426C>G p.N142K | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56967826; called by muse, mutect2, varscan2
- MELTF | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV56380874; called by muse, mutect2
- MIOX | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as rs752188540, COSV53312799; called by muse, mutect2
- NINL | c.3648G>T p.Q1216H | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV54001956; called by muse, mutect2, varscan2
- PCDH15 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs1179734691, COSV57301782, COSV57343122; called by muse, mutect2, varscan2
- PEG3 | c.3723T>G p.N1241K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.338); catalogued as COSV55632083; called by muse, mutect2, varscan2
- PTPN7 | c.1077C>G p.S359R (on ENST00000495688; = p.S398R on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV55343212; called by muse, mutect2, varscan2
- S100A12 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV64199125; called by muse, mutect2, varscan2
- SCAF8 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.941); catalogued as COSV65791481; called by muse, mutect2, varscan2
- SIK2 | c.1575C>G p.D525E | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59251970; called by muse, mutect2, varscan2
- SLC22A6 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV64560135; called by mutect2, varscan2
- SOS2 | c.1426A>C p.T476P | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV53566994; called by muse, mutect2, varscan2
- UHRF2 | c.176T>C p.F59S | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52792472; called by muse, mutect2
- USH2A | c.9699T>G p.N3233K | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV56362934; called by muse, mutect2, varscan2
- VHL | c.391A>T p.N131Y | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56549082; called by muse, mutect2, varscan2
- EGR2 | c.788del p.T263Ifs*18 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by pindel, varscan2
- EIF2B3 | c.734del p.G245Dfs*9 | Frame Shift Del (DEL) | VAF 44/261 reads (17%) | called by mutect2, pindel, varscan2
- KDM5C | c.1916dup p.Y639* | Nonsense Mutation (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- LAMA4 | c.432del p.E144Dfs*54 | Frame Shift Del (DEL) | VAF 100/506 reads (20%) | called by mutect2, pindel, varscan2
- NTRK1 | c.1396del p.L466Cfs*4 | Frame Shift Del (DEL) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- SRGAP1 | c.1179dup p.E394Rfs*4 | Frame Shift Ins (INS) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- ZNF528 | c.722del p.Y241Sfs*100 | Frame Shift Del (DEL) | VAF 28/191 reads (15%) | called by mutect2, pindel, varscan2
- CEP120 | c.2655T>A p.L885= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV60265309; called by muse, mutect2, varscan2
- FAM83B | c.477T>C p.D159= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as COSV60921650; called by muse, mutect2, varscan2
- FLNB | c.5256G>A p.P1752= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs773899543, COSV55878287; ClinVar: likely benign; called by muse, mutect2, varscan2
- HNRNPH1 | c.387G>A p.Q129= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as rs1444611924, COSV61485564; called by muse, mutect2, varscan2
- IGHD1-26 | c.20C>A p.*7= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs566830097; called by muse, mutect2
- IGSF9B | c.1020C>A p.I340= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58067021; called by muse, varscan2
- KMT2D | c.14877C>G p.A4959= | Silent (SNP) | VAF 31/200 reads (16%) | catalogued as COSV56435276; called by muse, mutect2, varscan2
- PLBD1 | c.1653T>C p.D551= | Silent (SNP) | VAF 44/245 reads (18%) | catalogued as COSV53693108; called by muse, mutect2, varscan2
- PLCB4 | c.1395G>T p.L465= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV53800237; called by muse, mutect2, varscan2
- TGM1 | c.243C>T p.G81= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV52862985; called by muse, mutect2, varscan2
- ZNF302 | c.1164A>G p.Q388= (on ENST00000627982; = p.Q309= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as rs754809081, COSV71063494; called by muse, mutect2, varscan2
